Somatic mutation profile of tumor specimen TCGA-G4-6295-01A (aliquot TCGA-G4-6295-01A-11D-1719-10) from TCGA case TCGA-G4-6295, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 70.5 years (25,758 days).
Specimen TCGA-G4-6295-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 623fed2d-999c-4962-96cd-e8c295a72f9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6295-10A (Blood Derived Normal), aliquot TCGA-G4-6295-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8edf8725-05c4-4b7c-a813-ab5b4ce4383c

The open-access MAF lists 157 somatic variants for this specimen: 123 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 32, Nonsense Mutation 6, Splice Site 4, Frame Shift Del 3, In Frame Del 2, Intron 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.5782G>C p.V1928L | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as COSV70025927, COSV70040945; called by muse, mutect2, varscan2
- ABHD3 | c.144C>G p.Y48* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV56677918; called by muse, mutect2, varscan2
- ADNP | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 75/636 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs758615541, COSV62426522; called by muse, mutect2, varscan2
- AFF2 | c.1090A>T p.M364L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as COSV54002035; called by muse, mutect2, varscan2
- AK7 | c.1486+2T>A p.X496_splice | Splice Site (SNP) | VAF 60/225 reads (27%) | catalogued as COSV50879223; called by muse, mutect2, varscan2
- ALK | c.2575G>C p.E859Q | Missense Mutation (SNP) | VAF 69/293 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66584425; called by muse, mutect2, varscan2
- ALPK2 | c.3476C>A p.T1159K | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.099); catalogued as rs528793765, COSV64494591, COSV64495832; called by muse, mutect2, varscan2
- ALYREF | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58669003; called by muse, mutect2, varscan2
- AMER1 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 58/154 reads (38%) | catalogued as COSV57665391; called by muse, varscan2
- APC | c.4391_4394del p.E1464Vfs*8 | Frame Shift Del (DEL) | VAF 34/117 reads (29%) | catalogued as rs387906234; called by mutect2, pindel, varscan2
- ARAP1 | c.3377G>T p.R1126L (on ENST00000393609 / NM_001040118.2; = p.R881L on NM_015242.4) | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs373421125, COSV61993894; called by muse, mutect2, varscan2
- CACNA1D | c.6209G>C p.G2070A (on ENST00000350061 / NM_001128840.3; = p.G2090A on NM_000720.4) | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); catalogued as COSV55460031; called by muse, mutect2, varscan2
- CAPN2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs992765811, COSV54338773; called by muse, mutect2, varscan2
- CARD6 | c.1260G>T p.M420I | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54568216; called by muse, mutect2, varscan2
- CD1D | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV63809673; called by muse, mutect2, varscan2
- CDAN1 | c.1078T>A p.F360I | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as CM060011, COSV99141013, COSV99141390; called by muse, mutect2
- CHODL | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as COSV100166887, COSV54734499; called by muse, mutect2, varscan2
- CLCNKA | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 128/361 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762493511, COSV58893392; called by muse, mutect2, varscan2
- CLPB | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53632485; called by muse, mutect2, varscan2
- CNGA3 | c.387A>T p.R129S | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55627111; called by muse, mutect2, varscan2
- COLGALT1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); catalogued as COSV53110971; called by muse, mutect2, varscan2
- COMMD9 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs145482286; called by muse, varscan2
- CRYBG2 | c.3563A>T p.D1188V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100366624; called by muse, mutect2, varscan2
- CUBN | c.7542T>A p.N2514K | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64724092; called by muse, mutect2, varscan2
- CXCL16 | c.302-2A>G p.X101_splice | Splice Site (SNP) | VAF 17/40 reads (43%) | catalogued as COSV53412012; called by muse, mutect2, varscan2
- DAO | c.115T>G p.F39V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57324046; called by muse, mutect2, varscan2
- DCAF12L2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 124/250 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1047080686, COSV63580676, COSV63584176; called by muse, mutect2, varscan2
- DIP2C | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55173837; called by muse, mutect2, varscan2
- DNAH3 | c.6769G>C p.D2257H | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV54543194; called by muse, mutect2, varscan2
- DNAH5 | c.5749C>G p.L1917V | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV54245009; called by muse, mutect2, varscan2
- DUSP29 | c.297C>G p.D99E | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV58301331; called by muse, mutect2, varscan2
- DUSP6 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV54379330; called by muse, mutect2, varscan2
- DYNC1H1 | c.12287T>A p.L4096Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64140750; called by muse, varscan2
- DYNC1H1 | c.12326T>C p.L4109P | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64140755; called by muse, varscan2
- EFEMP1 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 71/500 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.069); catalogued as COSV62617478; called by muse, mutect2, varscan2
- EPHX1 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs761149789, COSV55303155; called by muse, mutect2, varscan2
- FAM214B | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs746473903, COSV59717235; called by muse, mutect2, varscan2
- FBP1 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as COSV64689854; called by muse, mutect2, varscan2
- FGD5 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs775354263, COSV99547909; called by muse, mutect2, varscan2
- FHOD1 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99264058; called by muse, mutect2, varscan2
- FIZ1 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV55608829; called by muse, mutect2, varscan2
- FRK | c.549T>G p.F183L | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745410841, COSV101606645; called by muse, mutect2
- FRY | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.058); catalogued as COSV66576657; called by muse, mutect2, varscan2
- GLI1 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV99954056; called by muse, mutect2, varscan2
- GPAA1 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 56/464 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV60156331; called by muse, mutect2, varscan2
- GPR179 | c.3080G>A p.R1027Q (on ENST00000621958; = p.R1026Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs751002235; called by muse, mutect2, varscan2
- GRHL2 | c.766A>C p.K256Q | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as COSV99306751; called by muse, mutect2
- HABP4 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as rs1420051493, COSV64514560; called by muse, mutect2, varscan2
- HCN4 | c.2995C>T p.R999W | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs538668505, COSV56086382; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPHL1 | c.1451T>C p.L484S | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV59895095; called by muse, mutect2, varscan2
- HGF | c.255-2A>G p.X85_splice | Splice Site (SNP) | VAF 53/179 reads (30%) | catalogued as COSV55954787; called by muse, mutect2, varscan2
- HLA-DPA1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs371532700; called by muse, mutect2, varscan2
- HTR7 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as COSV53288858, COSV53291558; called by muse, mutect2, varscan2
- IL7R | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.394); catalogued as rs1374760636, COSV57411846; called by muse, mutect2, varscan2
- KCNQ3 | c.1911C>A p.D637E | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756450456, COSV66478944; called by muse, mutect2, varscan2
- KLHL11 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV59862863; called by muse, varscan2
- KMT2D | c.10267C>A p.P3423T | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56473851; called by muse, mutect2, varscan2
- LMTK2 | c.1768A>C p.T590P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52001698; called by muse, mutect2, varscan2
- LRRIQ1 | c.4213G>T p.V1405F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as COSV67836491; called by muse, mutect2, varscan2
- LSR | c.1906C>G p.L636V (on ENST00000361790; = p.L617V on NM_015925.6) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV55887873; called by muse, mutect2, varscan2
- MARK3 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); catalogued as COSV53514473; called by muse, mutect2, varscan2
- MCCD1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV66020164; called by muse, mutect2, varscan2
- METTL16 | c.929A>T p.K310I | Missense Mutation (SNP) | VAF 109/185 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV54015500; called by muse, mutect2, varscan2
- MRPS27 | c.837G>A p.A279= | Splice Region (SNP) | VAF 62/164 reads (38%) | catalogued as rs188024126, COSV99782151; called by muse, mutect2, varscan2
- MRPS9 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.015); catalogued as COSV51521009; called by muse, mutect2, varscan2
- MSLN | c.1352C>A p.S451Y (on ENST00000382862 / NM_013404.4; = p.S443Y on NM_005823.6) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV53505240, COSV99558676; called by muse, mutect2, varscan2
- MSN | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64305162; called by muse, mutect2, varscan2
- MYBL1 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 443/623 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs763361530, COSV72919156; called by muse, mutect2, varscan2
- MYBPH | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769884152, COSV55142915; called by muse, mutect2, varscan2
- MYH9 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV99338639; called by muse, mutect2, varscan2
- NF1 | c.4577+1G>C p.X1526_splice (on ENST00000358273 / NM_001042492.3; = p.X1505_splice on NM_000267.3) | Splice Site (SNP) | VAF 34/86 reads (40%) | catalogued as CS000878, COSV62210181; called by muse, mutect2, varscan2
- ODF2 | c.1842A>T p.Q614H (on ENST00000434106 / NM_153433.2; = p.Q590H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV63545743, COSV63547401, COSV63548473; called by muse, mutect2, varscan2
- OPRM1 | c.93G>A p.W31* | Nonsense Mutation (SNP) | VAF 39/73 reads (53%) | catalogued as COSV57682833; called by muse, mutect2, varscan2
- OR10A4 | c.201G>T p.L67F | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV101139505; called by muse, mutect2
- OR2L2 | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 215/638 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1381428216, COSV63558787; called by muse, mutect2, varscan2
- OR4C15 | c.261C>A p.Y87* (on ENST00000314644; = p.Y33* on NM_001001920.2) | Nonsense Mutation (SNP) | VAF 32/119 reads (27%) | catalogued as COSV58954863; called by muse, mutect2, varscan2
- OTOP2 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748057192, COSV100508878, COSV58882263; called by muse, mutect2, varscan2
- PAOX | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs753690252, COSV53373969; called by muse, mutect2, varscan2
- PCDHB2 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs146202039, COSV52036281; called by muse, mutect2, varscan2
- PDYN | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV54101877, COSV54103082; called by muse, mutect2, varscan2
- PGAP6 | c.830G>A p.W277* | Nonsense Mutation (SNP) | VAF 78/305 reads (26%) | catalogued as COSV51741667; called by muse, mutect2, varscan2
- PIK3CA | c.1974G>T p.L658F | Missense Mutation (SNP) | VAF 137/688 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55971959, COSV99841668; called by muse, mutect2, varscan2
- PPP1R12A | c.2098A>T p.T700S | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54112398; called by muse, mutect2, varscan2
- PPP1R3D | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62564576; called by muse, mutect2, varscan2
- PRKG1 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100907243; called by muse, mutect2
- PTP4A1 | c.344T>A p.V115D | Missense Mutation (SNP) | VAF 113/209 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65715452; called by muse, mutect2, varscan2
- PTPRC | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.052); catalogued as COSV61418859; called by muse, mutect2, varscan2
- PUS10 | c.874G>C p.G292R | Missense Mutation (SNP) | VAF 88/520 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57454278; called by muse, mutect2, varscan2
- SLC2A6 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs892330468, COSV64143156; called by muse, mutect2, varscan2
- SLC30A2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs149723161; called by muse, mutect2, varscan2
- SMAD9 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs759141619, COSV63206125; called by muse, mutect2, varscan2
- SSH1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1222844460, COSV58457131; called by muse, mutect2, varscan2
- STX4 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as rs1358538375, COSV58269130; called by muse, mutect2, varscan2
- SVOP | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs753922905, COSV100139163; called by muse, mutect2, varscan2
- SYCE2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs202219513; called by muse, mutect2, varscan2
- SYT17 | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs995820373, COSV62547667; called by muse, mutect2, varscan2
- TANGO6 | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 138/535 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99936063; called by muse, mutect2, varscan2
- TBC1D10C | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs565700309, COSV56704635; called by muse, mutect2, varscan2
- TBC1D8 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.607); catalogued as COSV65215474; called by muse, mutect2, varscan2
- TFAP2A | c.128G>T p.S43I (on ENST00000482890; = p.S35I on NM_001032280.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV60236797; called by muse, mutect2, varscan2
- TG | c.6938G>T p.G2313V | Missense Mutation (SNP) | VAF 51/416 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55069077, COSV55089912; called by muse, mutect2, varscan2
- TMC5 | c.504C>G p.S168R | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV66868034; called by muse, mutect2, varscan2
- TOGARAM1 | c.2614A>G p.K872E | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV63894179; called by muse, mutect2, varscan2
- TONSL | c.3203T>A p.L1068Q | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV68049074; called by muse, mutect2, varscan2
- TPTE | c.284G>T p.G95V (on ENST00000618007 / NM_199261.4; = p.G77V on NM_199259.4) | Missense Mutation (SNP) | VAF 461/1947 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs747276081; called by muse, mutect2, varscan2
- TPTE | c.841G>A p.V281I (on ENST00000618007 / NM_199261.4; = p.V263I on NM_199259.4) | Missense Mutation (SNP) | VAF 39/372 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.359); catalogued as rs773573743; called by muse, mutect2, varscan2
- TRIM49 | c.219G>C p.M73I | Missense Mutation (SNP) | VAF 179/1825 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV100316030, COSV61671630; called by muse, mutect2, varscan2
- TRPS1 | c.1904G>C p.S635T (on ENST00000220888 / NM_001330599.2; = p.S648T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 505/877 reads (58%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV55256261; called by muse, mutect2, varscan2
- TUBGCP6 | c.1963T>C p.S655P | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV50572128; called by muse, mutect2, varscan2
- USP31 | c.3302C>T p.P1101L | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs566732624, COSV99565093; called by muse, mutect2, varscan2
- WDHD1 | c.1469C>G p.A490G | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs145521075; called by muse, mutect2, varscan2
- WNT5A | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs533153165, COSV52838917; called by muse, mutect2, varscan2
- ZFHX4 | c.8437G>T p.A2813S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.965); catalogued as COSV51487212; called by muse, mutect2, varscan2
- ZFYVE28 | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV99342847; called by muse, varscan2
- ZNF326 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV61036053; called by muse, mutect2, varscan2
- ZNF638 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as rs374546224; called by muse, mutect2, varscan2
- ZNF793 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761931337, COSV71325146; called by muse, mutect2, varscan2
- ARID2 | c.5042_5043del p.S1681Ffs*8 | Frame Shift Del (DEL) | VAF 150/426 reads (35%) | called by pindel, varscan2
- IRF6 | c.164_172del p.T55_F57del | In Frame Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- MMADHC | c.741_773del p.E247_D257del | In Frame Del (DEL) | VAF 144/534 reads (27%) | called by mutect2, pindel
- SPATA31A1 | c.3694G>T p.V1232L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBX3 | c.583dup p.E195Gfs*32 (on ENST00000257566 / NM_016569.4; = p.E195Gfs*45 on NM_005996.4) | Frame Shift Ins (INS) | VAF 193/476 reads (41%) | called by mutect2, pindel, varscan2
- TP53 | c.452_459del p.P151Rfs*27 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- ABCB8 | c.1893G>C p.T631= (on ENST00000297504 / NM_001282291.2; = p.T614= on NM_007188.5) | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs144112099, COSV52509010; called by muse, mutect2, varscan2
- ADGRB1 | c.3966C>T p.D1322= | Silent (SNP) | VAF 26/216 reads (12%) | catalogued as rs369644974; called by muse, mutect2, varscan2
- AGRN | c.5949G>A p.T1983= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs748240272, COSV65070142; called by muse, mutect2, varscan2
- AKAP6 | c.5796T>C p.H1932= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as COSV55227746; called by muse, mutect2, varscan2
- ARHGEF40 | c.3009C>G p.A1003= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV53883224; called by muse, mutect2, varscan2
- CENPM | c.516T>A p.S172= | Silent (SNP) | VAF 48/173 reads (28%) | catalogued as COSV53245622; called by muse, mutect2, varscan2
- CEP350 | c.762A>T p.L254= | Silent (SNP) | VAF 35/179 reads (20%) | catalogued as COSV62486161; called by muse, mutect2, varscan2
- CFAP53 | c.435G>A p.R145= | Silent (SNP) | VAF 192/560 reads (34%) | catalogued as rs778888775, COSV68352648; called by muse, mutect2, varscan2
- COL6A2 | c.2802C>T p.G934= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs151295731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRTC1 | c.483G>A p.T161= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs765028098, COSV58722138; called by muse, mutect2, varscan2
- DCLRE1A | c.2097G>A p.K699= | Silent (SNP) | VAF 124/441 reads (28%) | catalogued as COSV100800330; called by muse, mutect2, varscan2
- DRD2 | c.150C>T p.F50= | Silent (SNP) | VAF 60/271 reads (22%) | catalogued as rs767660986, COSV100670313, COSV60761652; called by muse, mutect2, varscan2
- EFEMP1 | c.228G>A p.Q76= | Silent (SNP) | VAF 71/497 reads (14%) | catalogued as COSV62617470; called by muse, mutect2, varscan2
- EFHC2 | c.837C>T p.L279= | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as COSV69555063; called by muse, mutect2, varscan2
- FASTKD1 | c.783C>T p.D261= | Silent (SNP) | VAF 65/313 reads (21%) | catalogued as rs1204299133, COSV70007175; called by muse, mutect2, varscan2
- FAT2 | c.9258G>A p.K3086= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV55826933, COSV99942835; called by muse, mutect2, varscan2
- HPS5 | c.690G>C p.G230= (on ENST00000349215 / NM_181507.2; = p.G116= on NM_007216.4) | Silent (SNP) | VAF 73/276 reads (26%) | catalogued as COSV62540412; called by muse, mutect2, varscan2
- HYDIN | c.15288G>C p.L5096= | Silent (SNP) | VAF 87/341 reads (26%) | catalogued as COSV66638552, COSV66641468; called by muse, mutect2, varscan2
- ITGA4 | c.90C>T p.T30= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV52003003; called by muse, mutect2, varscan2
- LRRN3 | c.1698G>A p.A566= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as rs761438479, COSV57817747; called by muse, mutect2, varscan2
- MESP2 | c.903G>A p.L301= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV59093370; called by muse, mutect2, varscan2
- PIK3C2G | c.1101G>A p.Q367= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV56826645, COSV56839563; called by muse, mutect2, varscan2
- RBL1 | c.1710C>T p.H570= | Silent (SNP) | VAF 58/592 reads (10%) | catalogued as rs751661963, COSV60332645; called by muse, mutect2
- SELENON | c.207G>T p.G69= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as COSV100823495; called by muse, mutect2, varscan2
- SGCE | c.993A>G p.L331= (on ENST00000647096; = p.L295= on NM_003919.3) | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV56019511; called by muse, mutect2, varscan2
- SLC46A1 | c.471C>T p.F157= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV58708071; called by muse, mutect2, varscan2
- STAT2 | c.1008T>G p.T336= | Silent (SNP) | VAF 64/264 reads (24%) | catalogued as COSV58476864; called by muse, mutect2, varscan2
- STXBP5L | c.1728G>A p.P576= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs757374953, COSV56502473; called by muse, mutect2, varscan2
- TNFRSF1A | c.888C>T p.S296= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as COSV50608688; called by muse, mutect2, varscan2
- XKR7 | c.1422G>A p.R474= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV73813386; called by muse, mutect2, varscan2
- ZFPM1 | c.432C>T p.D144= | Silent (SNP) | VAF 192/344 reads (56%) | catalogued as rs893955692, COSV60326242; called by mutect2, varscan2
- ZSWIM1 | c.399G>A p.K133= | Silent (SNP) | VAF 381/628 reads (61%) | catalogued as COSV54850404; called by muse, mutect2, varscan2
- CSPP1 | c.535-1732T>G | Intron (SNP) | VAF 58/347 reads (17%) | catalogued as COSV99138406; called by muse, mutect2, varscan2
- MAGI1 | c.3635-1972G>C | Intron (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100440603; called by muse, mutect2, varscan2
